Somatic mutation profile of tumor specimen BA2666D (aliquot aq-BA2666D) from BEATAML1.0 case 2502, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 77.3 years (28,221 days).
Specimen BA2666D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90229c52-f941-4944-90d3-56bf03ca90b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2710D (Solid Tissue Normal), aliquot aq-BA2710D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3f8ecab-57b7-4f8d-a7b9-839340eda159

The open-access MAF lists 19 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Intron 3, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 81/292 reads (28%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCG8 | c.1720G>T p.G574W | Missense Mutation (SNP) | VAF 61/107 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM003584; called by muse, mutect2, varscan2
- CSNK2A2 | c.842G>T p.R281L | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as COSV99345172; called by muse, mutect2
- ITGB5 | c.361G>A p.G121S | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs774698322; called by muse, mutect2, varscan2
- MYH3 | c.4904G>A p.R1635H | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.159); catalogued as rs774787864, COSV56866338, COSV99878836; called by muse, mutect2, varscan2
- TNFRSF11A | c.1759C>T p.R587C | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as rs1270501227; called by muse, mutect2
- AC004922.1 | c.1822G>C p.A608P | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.029); called by muse, mutect2
- DDX20 | c.962G>A p.R321K | Missense Mutation (SNP) | VAF 53/102 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- DNAH10 | c.5169A>T p.R1723S (on ENST00000409039; = p.R1662S on NM_207437.3) | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- JAG2 | c.2429G>T p.W810L | Missense Mutation (SNP) | VAF 110/330 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MSC | c.247G>T p.A83S | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.025); called by muse, mutect2
- PLPBP | c.101A>G p.D34G | Missense Mutation (SNP) | VAF 62/124 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.005); called by muse, varscan2
- ZNF710 | c.474G>A p.M158I | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- ATXN1 | c.165C>T p.H55= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs750358073, COSV55212911; called by muse, varscan2
- NEB | c.5040C>T p.Y1680= | Silent (SNP) | VAF 14/45 reads (31%) | called by muse, mutect2
- ZRSR2 | c.285G>A p.A95= | Silent (SNP) | VAF 67/192 reads (35%) | catalogued as rs753178333; called by muse, mutect2, varscan2
- IGFN1 | c.1242-829C>A | Intron (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- SYNE2 | c.18038+865G>C | Intron (SNP) | VAF 50/93 reads (54%) | called by muse, mutect2, varscan2
- TBX3 | c.718-11T>G | Intron (SNP) | VAF 46/174 reads (26%) | called by muse, mutect2, varscan2
